Somatic mutation profile of tumor specimen TCGA-BT-A20P-01A (aliquot TCGA-BT-A20P-01A-11D-A14W-08) from TCGA case TCGA-BT-A20P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 81.1 years (29,634 days).
Specimen TCGA-BT-A20P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d9ab77a-85d5-4487-8c1e-c0dfc7860271.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20P-11A (Solid Tissue Normal), aliquot TCGA-BT-A20P-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cfdf510-822d-4966-9567-5afea90d1607

The open-access MAF lists 94 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 19, Nonsense Mutation 9, Frame Shift Del 3, Nonstop Mutation 2, Frame Shift Ins 1, 3'Flank 1, RNA 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.4298G>C p.R1433T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV52220074, COSV52222386; called by muse, mutect2, varscan2
- ABCC11 | c.789C>G p.F263L | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV62323231; called by muse, mutect2, varscan2
- C16orf87 | c.386C>G p.S129C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53511960; called by muse, mutect2, varscan2
- CAMK2G | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV59482090, COSV99989336; called by muse, varscan2
- CHD8 | c.4592G>A p.R1531H (on ENST00000646647 / NM_001170629.2; = p.R1252H on NM_020920.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs192277407, COSV63219166; called by muse, mutect2, varscan2
- CHODL | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54732750; called by muse, mutect2, varscan2
- COL12A1 | c.2569C>A p.Q857K | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59396402; called by muse, varscan2
- COPS7A | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV57526681; called by muse, mutect2, varscan2
- COX20 | c.343A>G p.S115G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1322874143, COSV63673454; called by muse, mutect2, varscan2
- CYP2R1 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV58127650; called by muse, mutect2, varscan2
- DCC | c.3536C>A p.P1179H | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71432396; called by muse, mutect2, varscan2
- DEPDC5 | c.3115A>C p.S1039R (on ENST00000400246; = p.S1108R on NM_014662.5) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.613); catalogued as COSV56697932; called by muse, mutect2, varscan2
- EDEM1 | c.1326C>A p.F442L | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV56581936; called by muse, mutect2, varscan2
- EDEM1 | c.1527C>G p.F509L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56581942; called by muse, mutect2, varscan2
- EIF4A3 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53920609; called by muse, mutect2, varscan2
- EPRS1 | c.2626C>T p.Q876* | Nonsense Mutation (SNP) | VAF 76/144 reads (53%) | catalogued as rs1442224285; called by muse, mutect2, varscan2
- FKBP15 | c.2280G>C p.E760D | Missense Mutation (SNP) | VAF 64/79 reads (81%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV53035020; called by muse, mutect2, varscan2
- FOXD4 | c.1037G>C p.G346A | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.873); catalogued as COSV58700360; called by muse, mutect2, varscan2
- GPRASP1 | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT tolerated (0.13); PolyPhen benign (0.348); catalogued as COSV64355626; called by muse, mutect2, varscan2
- GRM7 | c.2576G>A p.R859Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs369197989; called by muse, mutect2, varscan2
- H1-0 | c.445A>C p.K149Q | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1207094993, COSV50649056; called by muse, mutect2, varscan2
- H2BC1 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs199691595, COSV51237313; called by muse, mutect2, varscan2
- HMGB2 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV56633115, COSV56633610; called by muse, mutect2, varscan2
- ITGA7 | c.2524C>T p.R842* (on ENST00000555728; = p.R798* on NM_002206.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 135/220 reads (61%) | catalogued as rs755438542; called by muse, mutect2, varscan2
- KDM6A | c.3320del p.P1107Lfs*13 | Frame Shift Del (DEL) | VAF 24/30 reads (80%) | catalogued as COSV65045545; called by mutect2, varscan2
- KIAA0100 | c.6274C>T p.R2092C | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756175527, COSV56382119; called by muse, mutect2, varscan2
- KLK12 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.665); catalogued as rs772863503, COSV51577202; called by muse, mutect2, varscan2
- KPNA5 | c.1498C>G p.L500V | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs557995008, COSV62652556; called by muse, mutect2, varscan2
- LAMA3 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV58069114; called by muse, mutect2, varscan2
- MACF1 | c.11239G>C p.E3747Q (on ENST00000372915; = p.E1680Q on NM_012090.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV57122069; called by muse, mutect2, varscan2
- MACF1 | c.11436G>A p.M3812I (on ENST00000372915; = p.M1745I on NM_012090.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV57122095; called by muse, mutect2, varscan2
- MEI1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55903172; called by muse, mutect2, varscan2
- MICAL3 | c.5530G>C p.E1844Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV71588351; called by muse, mutect2, varscan2
- MRGBP | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65111441; called by muse, mutect2, varscan2
- MYH2 | c.3923C>G p.S1308* | Nonsense Mutation (SNP) | VAF 27/31 reads (87%) | catalogued as COSV55441574, COSV55447854; called by muse, mutect2, varscan2
- MYO15A | c.10498G>T p.E3500* | Nonsense Mutation (SNP) | VAF 24/30 reads (80%) | catalogued as rs763755567; called by muse, mutect2, varscan2
- NAT1 | c.486C>G p.D162E | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56985255; called by muse, mutect2, varscan2
- NEO1 | c.1421C>G p.S474C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56071409; called by muse, mutect2, varscan2
- NF1 | c.5665G>A p.E1889K (on ENST00000358273 / NM_001042492.3; = p.E1868K on NM_000267.3) | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs764782945, CM143443, COSV62193500, COSV62204278, COSV62222668; called by muse, mutect2, varscan2
- NOB1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs367776601, COSV52061722; called by muse, mutect2, varscan2
- NOTCH3 | c.5386G>T p.A1796S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54635226; called by muse, mutect2
- OR2H2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63542574; called by muse, mutect2, varscan2
- PCDHAC1 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53850275; called by muse, mutect2, varscan2
- PRRC2A | c.2077C>A p.P693T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV65686633; called by muse, mutect2, varscan2
- PRX | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.291); catalogued as COSV52530086; called by muse, varscan2
- PRX | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as COSV52530093; called by muse, mutect2, varscan2
- RAVER2 | c.896G>A p.G299D | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs186869355; called by muse, mutect2, varscan2
- RPGRIP1L | c.610G>C p.A204P | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV50907100; called by muse, varscan2
- SENP7 | c.1134G>C p.L378F | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58612202; called by muse, varscan2
- SLC1A2 | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53521552, COSV99555183; called by muse, mutect2, varscan2
- SLC5A7 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50891903; called by muse, mutect2, varscan2
- SPACA7 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV52100153; called by muse, mutect2, varscan2
- SYCP2 | c.4540C>T p.R1514C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs763101543, COSV62768503; called by muse, mutect2, varscan2
- TACC3 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 87/92 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763476598, COSV57605005; called by muse, mutect2, varscan2
- TMTC2 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.545); catalogued as COSV58269198; called by muse, mutect2, varscan2
- VPS13C | c.8860G>C p.V2954L (on ENST00000644861 / NM_020821.3; = p.V2911L on NM_017684.5) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51185595; called by muse, mutect2, varscan2
- WNK3 | c.4789C>T p.R1597* | Nonsense Mutation (SNP) | VAF 50/91 reads (55%) | catalogued as COSV63615772; called by muse, mutect2, varscan2
- YIPF1 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50777338; called by muse, mutect2, varscan2
- ZBTB11 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV57245229; called by muse, varscan2
- ZNF25 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56922636; called by muse, mutect2, varscan2
- ZSCAN1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV56604604; called by muse, mutect2, varscan2
- ZSWIM2 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV54575565, COSV54575654; called by muse, mutect2, varscan2
- ELF3 | c.1033dup p.V345Gfs*126 | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- HLA-A | c.1115G>T p.*372Lext*8 (on ENST00000376806; = p.*366Lext*8 on NM_002116.8) | Nonstop Mutation (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2
- MGP | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | called by muse, varscan2
- MST1R | c.3361G>T p.E1121* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- PDXK | c.203del p.G68Afs*2 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- RIMKLB | c.1160G>C p.*387Sext*4 | Nonstop Mutation (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- TSC1 | c.1607T>A p.L536* | Nonsense Mutation (SNP) | VAF 26/32 reads (81%) | called by muse, mutect2, varscan2
- ZCCHC8 | c.405del p.F136Lfs*12 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- ZDHHC11 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- ADAM11 | c.1938G>C p.L646= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV52346424; called by muse, mutect2, varscan2
- ALDH1B1 | c.879C>T p.I293= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs141592792; called by muse, mutect2, varscan2
- BCL2L13 | c.234C>T p.F78= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as COSV58225861; called by muse, mutect2
- BTAF1 | c.2892C>A p.V964= | Silent (SNP) | VAF 35/74 reads (47%) | catalogued as COSV56434321; called by muse, mutect2, varscan2
- DISP3 | c.597G>C p.R199= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV53827831; called by muse, mutect2, varscan2
- DOCK4 | c.5130C>A p.S1710= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV70237146; called by muse, mutect2
- ECEL1 | c.2197C>T p.L733= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs764061807, COSV58812387; called by muse, mutect2, varscan2
- EIF4G2 | c.2172G>C p.L724= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs750040365, COSV60597165; called by muse, mutect2, varscan2
- EPHB3 | c.1518C>T p.N506= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV57806066; called by muse, mutect2, varscan2
- FAM9B | c.444G>A p.R148= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV59119507; called by muse, mutect2, varscan2
- FANCA | c.759G>C p.L253= | Silent (SNP) | VAF 58/126 reads (46%) | catalogued as COSV66881630; called by muse, mutect2, varscan2
- FUBP3 | c.942G>T p.A314= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV60514310, COSV60516692; called by muse, varscan2
- IFI16 | c.1722G>A p.Q574= (on ENST00000295809 / NM_001364867.2; = p.Q518= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs779668092, COSV55534275; called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIF21B | c.1950C>T p.I650= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs368106761, COSV59768825; called by muse, mutect2, varscan2
- MRGBP | c.243G>C p.L81= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV65111434; called by muse, mutect2, varscan2
- SNX33 | c.924G>C p.R308= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV57913570; called by muse, mutect2, varscan2
- STBD1 | c.840C>T p.F280= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV52953863; called by muse, mutect2, varscan2
- TLR4 | c.1296C>T p.S432= (on ENST00000355622 / NM_138554.5; = p.S392= on NM_003266.4) | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as COSV62923309; called by muse, mutect2, varscan2
- ACTRT3 | chr3:169764676 C>A | 3'Flank (SNP) | VAF 14/23 reads (61%) | called by muse, mutect2, varscan2
- DUSP13 | c.*504A>G | 3'UTR (SNP) | VAF 45/113 reads (40%) | catalogued as COSV57814523; called by muse, mutect2, varscan2
- FBXL21P | n.867G>C | RNA (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- RC3H2 | c.961-126G>C | Intron (SNP) | VAF 31/39 reads (79%) | catalogued as COSV100106232; called by muse, mutect2, varscan2
